FM case AD15671 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/72cdc6fb-9d41-4caa-beb3-01c3fef229c2

Male, 68.8 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the bladder; primary biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
